Somatic mutation profile of tumor specimen TCGA-MG-AAMC-01A (aliquot TCGA-MG-AAMC-01A-11D-A41K-08) from TCGA case TCGA-MG-AAMC, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 59.8 years (21,846 days).
Specimen TCGA-MG-AAMC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7cf69eba-23e1-4c2b-8b4d-505d6cbe87b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MG-AAMC-10A (Blood Derived Normal), aliquot TCGA-MG-AAMC-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0dea0339-c7f2-4351-99a0-306ba2d291a2

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 4, 5'UTR 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP9 | c.6479T>G p.L2160R (on ENST00000359028; = p.L2128R on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100661788; called by muse, mutect2, varscan2
- ATP10B | c.1108A>T p.T370S | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1254386090, COSV100468933; called by muse, mutect2, varscan2
- CD200R1 | c.729A>T p.L243F (on ENST00000471858 / NM_170780.3; = p.L266F on NM_138806.4) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.945); catalogued as COSV99866641; called by muse, mutect2, varscan2
- CMYA5 | c.3429T>A p.S1143R | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV101483731; called by muse, mutect2, varscan2
- DENND3 | c.3275C>T p.A1092V | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs143494640, COSV52802946; called by muse, mutect2, varscan2
- LRRC24 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1164813389, COSV99430108; called by muse, mutect2, varscan2
- MBLAC1 | c.122A>C p.D41A | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs771373915, COSV99498729; called by muse, varscan2
- NELL1 | c.1660T>C p.S554P | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100118028; called by muse, mutect2, varscan2
- RPA1 | c.1639C>A p.L547I | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.987); catalogued as COSV99627589; called by muse, mutect2, varscan2
- SETD2 | c.5996C>G p.P1999R | Missense Mutation (SNP) | VAF 74/191 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.374); catalogued as COSV100337762; called by muse, mutect2, varscan2
- SLCO2A1 | c.1316C>A p.P439Q | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.823); catalogued as rs147644142, COSV100188591; called by muse, mutect2, varscan2
- STING1 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs199795457; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBC1D10A | c.545T>C p.V182A | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99304416; called by muse, mutect2, varscan2
- TMEM132E | c.1329G>A p.W443* (on ENST00000321639; = p.W533* on NM_001304438.2) | Nonsense Mutation (SNP) | VAF 47/168 reads (28%) | catalogued as COSV100395878; called by muse, mutect2, varscan2
- TRIOBP | c.3755C>T p.S1252F | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.117); catalogued as rs560619122, COSV60374416; called by muse, mutect2
- TRPC4AP | c.188C>T p.T63M | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs200326780; called by muse, mutect2, varscan2
- ZNF746 | c.50C>T p.T17M | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs1356949548, COSV61407942; called by muse, mutect2, varscan2
- ESF1 | c.725_734del p.D242Afs*5 | Frame Shift Del (DEL) | VAF 24/85 reads (28%) | called by mutect2, pindel, varscan2
- ANKRD27 | c.72G>A p.L24= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV100042479; called by muse, mutect2, varscan2
- CATSPERG | c.2898C>T p.D966= | Silent (SNP) | VAF 99/267 reads (37%) | catalogued as rs2302184; called by muse, mutect2, varscan2
- DUOX1 | c.3919C>A p.R1307= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as rs368964201, COSV100367529; called by muse, mutect2, varscan2
- GSK3A | c.813C>T p.V271= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV99725021; called by muse, mutect2, varscan2
- VPS11 | c.-345G>T | 5'UTR (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100333460; called by muse, mutect2
